Somatic mutation profile of tumor specimen BLGSP-71-08-00048-01A (aliquot BLGSP-71-08-00048-01A-01D-A671-33) from CGCI case BLGSP-71-08-00048, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 4.0 years (1,450 days).
Specimen BLGSP-71-08-00048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e76f05ed-3beb-4d54-94f2-9435e71d6c58.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00048-10A (Blood Derived Normal), aliquot BLGSP-71-08-00048-10A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c614fb55-bfc1-4879-b836-8bfe421cbfb4

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 3, Silent 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.962C>A p.A321D (on ENST00000399959; = p.A322D on NM_001356.5) | Missense Mutation (SNP) | VAF 230/237 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863471; called by muse, mutect2, varscan2
- DSCAM | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.928); catalogued as rs371236113; called by muse, mutect2, varscan2
- MYC | c.433G>C p.V145L (on ENST00000377970; = p.V160L on NM_002467.6) | Missense Mutation (SNP) | VAF 126/233 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV99420693; called by muse, varscan2
- FBXO11 | c.2503T>C p.C835R (on ENST00000403359 / NM_001190274.2; = p.C751R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO11 | c.2173A>T p.N725Y (on ENST00000403359 / NM_001190274.2; = p.N641Y on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.9846A>C p.E3282D | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCBP1 | c.396_424del p.Q132Hfs*72 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- PMAIP1 | c.103_106del p.K35* | Frame Shift Del (DEL) | VAF 27/192 reads (14%) | called by mutect2, pindel, varscan2
- SIN3A | c.1072del p.V358Cfs*32 | Frame Shift Del (DEL) | VAF 40/257 reads (16%) | called by mutect2, pindel, varscan2
- SIN3A | c.556T>A p.L186M | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD83 | c.138G>T p.T46= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- MYC | c.513C>T p.C171= (on ENST00000377970; = p.C186= on NM_002467.6) | Silent (SNP) | VAF 106/331 reads (32%) | called by muse, varscan2
- MYC | c.687C>G p.S229= (on ENST00000377970; = p.S244= on NM_002467.6) | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as COSV52379897, COSV99422036; called by muse, varscan2
- CXCR4 | c.15+473C>T | Intron (SNP) | VAF 52/330 reads (16%) | called by muse, varscan2
- CXCR4 | c.15+452C>A | Intron (SNP) | VAF 62/316 reads (20%) | catalogued as COSV54011857; called by muse, varscan2
